Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1YA, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1YA-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY

ICD-0-3
papillary,
CQCF: carcinoma, follicular variant 8340/3
Path: Carcinoma, papillary thyroid 8260/3
Site: thyroid, NOS C73.9
3/4/11 *lw*

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: F

HCN:

Ordering

MD:

Copy To:

Location:

Facility:

Reported:

Specimen(s) Received

1. Thyroid: right hemi thyroidectomy, suture upper pole for tumor bank

Diagnosis

Papillary carcinoma 3.7 cm, arising in oncocytic follicular adenoma; underlying nodular hyperplasia;
Thyroid, right hemithyroidectomy specimen

Synoptic Data

Specimen Type:	Right Hemi-Thyroidectomy
Tumour Focality:	Unifocal
Histologic Type:	Papillary carcinoma, oncocytic type ok/lw
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 3.7 cm
	Additional Dimensions: 3.6 x 3.6 x 2.8 cm
Capsular Invasion:	Encapsulated
	Locally invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Pathologic Staging (pTNM):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
	pNX: Regional lymph nodes cannot be assigned
	pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	Nodular hyperplasia

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

Per TSS, TCGA tumor is 100% follicular variant.

Case is Circled	☐	☒

Electronically verified

, MD

by:

[page 2 of 2]
Gross Description

The specimen labeled with the patient's name and as "Thyroid: Right hemithyroidectomy, suture upper pole for tumor bank", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 36.7 g. The lobe measures 5.6 cm SI x 4.2 cm ML x 3.0 cm AP and the isthmus measures 1.3 SI x 0.5 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified. The external surface is painted with blue dye. The lobe contains two well delineated nodules; the superior one measures 1.8 cm SI x 1.0 cm ML x 1.5 cm AP and the inferior one measures 3.7 cm SI x 3.6-cm ML x 2.8 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-N lobe, superior to inferior
1O isthmus

Source: NCI Genomic Data Commons file 099e784e-1aac-4efb-842e-b81538af0292 (TCGA-EM-A1YA.2156B952-C5C8-40EF-BEE9-41C9B43D8A74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).